Somatic mutation profile of tumor specimen TCGA-EA-A1QT-01A (aliquot TCGA-EA-A1QT-01A-11D-A14W-08) from TCGA case TCGA-EA-A1QT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 47.8 years (17,475 days).
Specimen TCGA-EA-A1QT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85f21c64-b984-4a34-a15c-a48312e86460.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A1QT-10A (Blood Derived Normal), aliquot TCGA-EA-A1QT-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f5d6e85-3907-4142-b218-375611ecbe15

The open-access MAF lists 74 somatic variants for this specimen: 60 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 54, Silent 14, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.5036C>G p.S1679* | Nonsense Mutation (SNP) | VAF 47/59 reads (80%) | catalogued as rs1064796184, COSV61773224, COSV61775522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs147580372, COSV55748182; called by muse, mutect2, varscan2
- ABCB5 | c.865G>T p.V289L | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs373260063; called by muse, mutect2, varscan2
- ADAM30 | c.1058G>A p.C353Y | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65561480; called by muse, mutect2, varscan2
- ADGRG4 | c.2725A>T p.S909C | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54960497; called by muse, mutect2, varscan2
- ATL2 | c.874G>C p.G292R | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV60053666; called by muse, mutect2, varscan2
- BAIAP3 | c.3164G>A p.G1055D | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs1418810992, COSV50104332; called by muse, mutect2, varscan2
- BRAF | c.1322C>T p.T441I (on ENST00000288602 / NM_001374244.1; = p.T401I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56074952, COSV56248932; called by muse, mutect2, varscan2
- BRD4 | c.2214C>G p.H738Q | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated, low confidence (0.63); PolyPhen possibly damaging (0.88); catalogued as rs1488126563, COSV54589202; called by muse, varscan2
- C6 | c.982A>T p.K328* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as COSV54712771; called by muse, mutect2, varscan2
- CES5A | c.1126-1G>A p.X376_splice | Splice Site (SNP) | VAF 28/34 reads (82%) | catalogued as COSV51867894; called by muse, mutect2, varscan2
- CFAP47 | c.1348A>G p.K450E | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV52887499; called by muse, mutect2, varscan2
- CLTCL1 | c.1188G>T p.E396D | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54224940; called by muse, mutect2, varscan2
- CREBBP | c.4627G>C p.D1543H | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM065107, CM1414259, COSV52118192, COSV52122852, COSV52129653; called by muse, mutect2, varscan2
- CTNNA3 | c.582C>A p.D194E | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.165); catalogued as COSV65598758; called by muse, mutect2, varscan2
- CTTNBP2 | c.2561G>A p.G854D | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.602); catalogued as COSV50416688; called by muse, mutect2, varscan2
- EEF1AKNMT | c.959G>C p.G320A (on ENST00000361735 / NM_015935.5; = p.G234A on NM_014955.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV62283360; called by muse, mutect2
- ERBB4 | c.3693G>C p.E1231D | Missense Mutation (SNP) | VAF 68/89 reads (76%) | SIFT tolerated (0.43); PolyPhen benign (0.104); catalogued as COSV61499941, COSV61521084; called by muse, mutect2, varscan2
- FAM199X | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55434025; called by muse, mutect2, varscan2
- FAM71A | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as COSV54236204; called by muse, mutect2, varscan2
- FCRL1 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63826135; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1876A>G p.I626V | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV58558656; called by muse, mutect2, varscan2
- FRAS1 | c.6700G>A p.E2234K | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53602113; called by muse, mutect2, varscan2
- GBP4 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV63254944; called by muse, mutect2, varscan2
- GJA5 | c.545T>G p.L182R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54785008; called by muse, varscan2
- GLT1D1 | c.938T>A p.V313E (on ENST00000442111 / NM_001366889.1; = p.V233E on NM_144669.3) | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV55883849; called by muse, mutect2, varscan2
- HPR | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as COSV57183553; called by muse, mutect2, varscan2
- KCNAB1 | c.1156C>T p.L386F (on ENST00000490337 / NM_172160.3; = p.L375F on NM_003471.3) | Missense Mutation (SNP) | VAF 89/141 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV56748434; called by muse, mutect2, varscan2
- KLHL6 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376100820; called by muse, mutect2, varscan2
- LRP1 | c.2796A>G p.S932= | Splice Region (SNP) | VAF 2/9 reads (22%) | catalogued as COSV54516690; called by muse, mutect2
- MAP3K15 | c.3907G>A p.A1303T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV58826189, COSV58826657; called by muse, mutect2, varscan2
- NOTCH4 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs377458854; called by muse, mutect2, varscan2
- P2RY4 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as rs752641496, COSV65736829; called by muse, mutect2, varscan2
- PARP2 | c.444G>C p.W148C | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51640374; called by muse, mutect2, varscan2
- PAX1 | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as COSV68272440; called by muse, mutect2, varscan2
- PCDH11X | c.3950C>T p.S1317L | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); catalogued as rs1201676026, COSV53462412, COSV53480138; called by muse, mutect2, varscan2
- PHC1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs767832005, COSV50003253; called by muse, mutect2, varscan2
- PIK3C3 | c.1212A>C p.K404N | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56281256; called by muse, mutect2, varscan2
- PPP1R15B | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV65816031; called by muse, mutect2, varscan2
- PRKN | c.25T>G p.S9A | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as rs111356273, COSV58239349; called by muse, mutect2, varscan2
- PRPF40B | c.673G>A p.D225N (on ENST00000380281; = p.D219N on NM_012272.3) | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.407); catalogued as COSV56060193; called by muse, mutect2, varscan2
- PRPS2 | c.484T>A p.W162R | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV66126398; called by muse, mutect2, varscan2
- RWDD2A | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV52284684; called by muse, mutect2, varscan2
- SFXN5 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs373206510; called by muse, mutect2, varscan2
- SLC19A3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 63/75 reads (84%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367620430; called by muse, mutect2, varscan2
- SLITRK3 | c.1162T>G p.L388V | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV53848410, COSV53849947, COSV53850813; called by muse, mutect2, varscan2
- SRRM3 | c.890G>A p.S297N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58389021; called by muse, mutect2, varscan2
- TEAD2 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV60873988; called by muse, mutect2, varscan2
- TENM1 | c.5580T>A p.N1860K | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV64435936, COSV64440252; called by muse, mutect2, varscan2
- TMEM132A | c.2260C>T p.R754C (on ENST00000453848 / NM_178031.3; = p.R755C on NM_017870.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760024959, COSV50001729, COSV50010817; called by muse, mutect2, varscan2
- TRIM42 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as rs867368316, COSV53884407; called by muse, mutect2, varscan2
- TRIM69 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as rs761545728, COSV57804305; called by muse, mutect2, varscan2
- TTN | c.65776T>A p.Y21926N (on ENST00000591111; = p.Y14502N on NM_003319.4) | Missense Mutation (SNP) | VAF 69/146 reads (47%) | PolyPhen probably damaging (1); catalogued as COSV60164221; called by muse, mutect2, varscan2
- TUT4 | c.4717T>G p.F1573V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); catalogued as COSV57116234; called by muse, varscan2
- ZBTB38 | c.2554C>G p.H852D | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV58542649; called by muse, mutect2
- ZNF358 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV51177326; called by muse, mutect2, varscan2
- ZNF385A | c.692C>T p.A231V (on ENST00000338010 / NM_001130967.3; = p.A211V on NM_015481.3) | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207821822, COSV61493779; called by muse, mutect2, varscan2
- ABL1 | c.1360_1362del p.K454del | In Frame Del (DEL) | VAF 72/216 reads (33%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.2925del p.L976Sfs*2 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, varscan2
- KIR3DL3 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 88/290 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- ADAMTS14 | c.171G>A p.V57= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV64603708; called by muse, mutect2
- ANKFY1 | c.1338C>T p.R446= | Silent (SNP) | VAF 26/34 reads (76%) | catalogued as rs775180647, COSV58919230; called by muse, mutect2, varscan2
- CPAMD8 | c.1134C>T p.V378= (on ENST00000651564; = p.V331= on NM_015692.5) | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs764498786, COSV52236377, COSV52240995; called by muse, mutect2, varscan2
- IMPA1 | c.438A>G p.L146= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs749069269, COSV56271984; called by muse, mutect2, varscan2
- KCNA4 | c.162C>T p.S54= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs749000246, COSV60252647, COSV60253432, COSV60255384; called by muse, mutect2, varscan2
- MTMR9 | c.588G>A p.G196= | Silent (SNP) | VAF 17/21 reads (81%) | catalogued as COSV55313552; called by muse, mutect2, varscan2
- MUC2 | c.591G>A p.Q197= | Silent (SNP) | VAF 43/50 reads (86%) | called by muse, mutect2, varscan2
- MXI1 | c.105G>A p.P35= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs1391946430, COSV53292226; called by muse, mutect2, varscan2
- OR5M10 | c.432G>T p.L144= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV73242365; called by muse, mutect2, varscan2
- PCDH9 | c.2493C>T p.F831= | Silent (SNP) | VAF 57/77 reads (74%) | catalogued as rs775323783, COSV60530389, COSV60543623; called by muse, mutect2, varscan2
- ST18 | c.183C>G p.P61= | Silent (SNP) | VAF 67/159 reads (42%) | catalogued as COSV52499418, COSV52502625; called by muse, mutect2, varscan2
- TMEFF2 | c.27G>A p.Q9= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV55835112; called by muse, mutect2, varscan2
- TRIM56 | c.1530C>T p.I510= | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as COSV60159719; called by muse, mutect2, varscan2
- ZNF37A | c.51C>T p.F17= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs149074366; called by muse, mutect2, varscan2
